TARGET case TARGET-40-NAAWDP — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/4948cc83-841d-5630-a9ab-cb2156d5419e

Biospecimens (1 sample)
- Sample TARGET-40-NAAWDP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
